Somatic mutation profile of tumor specimen TCGA-60-2711-01A (aliquot TCGA-60-2711-01A-01D-1522-08) from TCGA case TCGA-60-2711, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.8 years (23,651 days).
Specimen TCGA-60-2711-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 592dc48d-44e0-4a1f-b7b4-68e13a636255.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2711-11A (Solid Tissue Normal), aliquot TCGA-60-2711-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/418ab370-151c-4882-9748-3e8759e018c0

The open-access MAF lists 135 somatic variants for this specimen: 90 protein-altering or splice-affecting, 36 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 36, Nonsense Mutation 10, Intron 5, RNA 4, Frame Shift Del 1, Splice Region 1, Nonstop Mutation 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACKR2 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs760448133, COSV56177645; called by muse, mutect2, varscan2
- BEST4 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 184/280 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs752957577, COSV64733724; called by muse, varscan2
- BLM | c.551A>T p.Q184L | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV61924046; called by muse, mutect2, varscan2
- BPHL | c.875G>C p.*292Sext*21 | Nonstop Mutation (SNP) | VAF 31/170 reads (18%) | catalogued as COSV61318812, COSV61318987; called by muse, mutect2, varscan2
- BPTF | c.4537A>G p.K1513E | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV58837086; called by muse, mutect2, varscan2
- C19orf73 | c.169G>C p.V57L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as COSV55521581; called by muse, mutect2, varscan2
- C3 | c.424G>C p.G142R | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55572786; called by muse, mutect2, varscan2
- CALCR | c.1448T>C p.I483T (on ENST00000649521 / NM_001164737.2; = p.I467T on NM_001742.4) | Missense Mutation (SNP) | VAF 12/380 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV64008036; called by muse, mutect2
- CASKIN1 | c.1371T>G p.Y457* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV58872508; called by muse, mutect2, varscan2
- CIART | c.341A>T p.E114V | Missense Mutation (SNP) | VAF 41/343 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51744024; called by muse, mutect2, varscan2
- CNNM2 | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV63998545; called by muse, mutect2, varscan2
- CNOT6 | c.1142C>G p.S381* | Nonsense Mutation (SNP) | VAF 62/222 reads (28%) | catalogued as COSV56161473; called by muse, mutect2, varscan2
- COL6A6 | c.2918G>T p.G973V | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV100650830, COSV62024971; called by muse, mutect2, varscan2
- CRACD | c.3381C>A p.V1127= | Splice Region (SNP) | VAF 43/114 reads (38%) | catalogued as COSV51720763, COSV99949035; called by muse, mutect2, varscan2
- CRTAC1 | c.826T>A p.F276I | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV54001482; called by muse, mutect2, varscan2
- CSMD3 | c.8941G>T p.G2981* (on ENST00000297405 / NM_001363185.1; = p.G2812* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 19/125 reads (15%) | catalogued as COSV52177014; called by muse, mutect2, varscan2
- CSMD3 | c.4280T>A p.L1427* (on ENST00000297405 / NM_001363185.1; = p.L1323* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 28/127 reads (22%) | catalogued as COSV52177029; called by muse, mutect2, varscan2
- CST4 | c.404A>T p.N135I | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs1417068736, COSV54149633; called by muse, mutect2, varscan2
- CTNND2 | c.1906G>A p.G636S | Missense Mutation (SNP) | VAF 53/370 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58887977; called by muse, mutect2, varscan2
- CWH43 | c.831C>A p.Y277* | Nonsense Mutation (SNP) | VAF 37/186 reads (20%) | catalogued as COSV56938755, COSV99894075; called by muse, mutect2, varscan2
- DAB2 | c.1751G>T p.W584L | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as COSV57914288; called by muse, mutect2, varscan2
- DAB2 | c.1303C>G p.Q435E | Missense Mutation (SNP) | VAF 36/334 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV57914299; called by muse, mutect2, varscan2
- DMWD | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 25/93 reads (27%) | catalogued as COSV52178103; called by muse, mutect2, varscan2
- DMWD | c.1152G>T p.E384D | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV52178110; called by muse, mutect2, varscan2
- DST | c.7085C>G p.S2362C | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.789); catalogued as COSV99753918; called by muse, mutect2, varscan2
- ENAM | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV68535911; called by muse, mutect2, varscan2
- FERD3L | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.272); catalogued as rs745337460, COSV51762516, COSV51764115; called by muse, mutect2, varscan2
- GPRIN3 | c.809T>A p.L270H | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV60884854; called by muse, varscan2
- H1-8 | c.996C>G p.I332M | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as COSV60711536; called by muse, mutect2, varscan2
- HCN1 | c.904A>T p.I302F | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV57509909; called by muse, mutect2, varscan2
- HERC2 | c.9633G>T p.E3211D | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55323140; called by muse, mutect2, varscan2
- IFNE | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 72/119 reads (61%) | catalogued as rs1296446711, COSV58640927; called by muse, mutect2, varscan2
- IGSF3 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1265587019, COSV59590609; called by muse, mutect2, varscan2
- LMX1B | c.725C>G p.S242W | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1002033502, CM042387, COSV62739570; called by muse, mutect2, varscan2
- MON1A | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as COSV56560481; called by muse, mutect2, varscan2
- MTNR1B | c.963G>T p.R321S | Missense Mutation (SNP) | VAF 92/447 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV57065532, COSV57066467; called by muse, mutect2, varscan2
- MUC4 | c.13724G>A p.G4575D (on ENST00000463781 / NM_018406.7; = p.G339D on NM_004532.6) | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs967598145, COSV57779728; called by muse, mutect2
- NELL2 | c.562A>T p.T188S | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV61574625; called by muse, mutect2, varscan2
- NSUN2 | c.1097T>A p.V366E | Missense Mutation (SNP) | VAF 150/419 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV52954269; called by muse, mutect2, varscan2
- OGDHL | c.70G>T p.V24F | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV65102331; called by muse, mutect2
- OR2A5 | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 176/529 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV68738629, COSV68738714; called by muse, varscan2
- OR2AG2 | c.425G>T p.W142L | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.515); catalogued as COSV58455122; called by muse, mutect2, varscan2
- OR4C15 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 66/355 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs750124773, COSV58952756; called by muse, mutect2, varscan2
- PCDHA11 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.16); catalogued as rs991131905, COSV56499175; called by muse, mutect2, varscan2
- PGM5 | c.1284C>A p.H428Q | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV67167636; called by muse, mutect2, varscan2
- PHACTR3 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 78/237 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as rs143288140, COSV63027760; called by muse, mutect2, varscan2
- PHKA2 | c.958C>T p.L320F | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV66053875; called by muse, mutect2
- PIK3CG | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV63246379; called by muse, mutect2, varscan2
- PIK3R6 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs753549112, COSV61003102; called by muse, mutect2, varscan2
- PIP5KL1 | c.697C>A p.P233T (on ENST00000388747 / NM_001135219.2; = p.P30T on NM_173492.1) | Missense Mutation (SNP) | VAF 66/98 reads (67%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV55944494, COSV55944522; called by muse, mutect2, varscan2
- PKHD1L1 | c.2980G>A p.G994R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199692519; called by muse, mutect2, varscan2
- PLG | c.2425A>G p.N809D | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1255238080, COSV57515114; called by muse, mutect2, varscan2
- PLPPR4 | c.1781A>G p.K594R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1467154077, COSV64565745; called by muse, mutect2, varscan2
- PPRC1 | c.2920A>G p.S974G | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs757124491, COSV53385291; called by muse, mutect2, varscan2
- PRB2 | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 149/1123 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.033); catalogued as rs1426583107, COSV66983042; called by muse, varscan2
- PRKCA | c.1404C>G p.N468K | Missense Mutation (SNP) | VAF 49/344 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52584362, COSV99434094; called by muse, mutect2, varscan2
- PROZ | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV61439377; called by muse, mutect2, varscan2
- PTK2 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 87/557 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs749253117, COSV61785583; called by muse, mutect2, varscan2
- RNF213 | c.15206G>C p.R5069T | Missense Mutation (SNP) | VAF 137/184 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs746137859, COSV60396399, COSV60397215; called by muse, mutect2, varscan2
- RSC1A1 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV60779686; called by muse, mutect2, varscan2
- RXRG | c.1364T>C p.M455T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV63232102; called by muse, varscan2
- SH2B2 | c.1613A>T p.H538L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV60826298; called by muse, mutect2, varscan2
- SLC12A7 | c.2179G>T p.V727L | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as COSV53757170, COSV53758965; called by muse, mutect2, varscan2
- SLC6A8 | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53472199; called by muse, mutect2, varscan2
- SLC7A2 | c.1147A>G p.K383E | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV50248327, COSV50252759; called by muse, mutect2, varscan2
- SLC7A9 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.633); catalogued as COSV50085094; called by muse, mutect2, varscan2
- SPAG17 | c.2143C>G p.P715A | Missense Mutation (SNP) | VAF 51/372 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as COSV60458575, COSV60462861; called by muse, mutect2, varscan2
- SPANXN1 | c.146C>A p.S49* | Nonsense Mutation (SNP) | VAF 56/228 reads (25%) | catalogued as rs1480759110, COSV65122400; called by muse, mutect2, varscan2
- SPINT2 | c.309G>T p.R103S | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV56647840; called by muse, mutect2, varscan2
- SPTBN5 | c.8215G>A p.E2739K | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.51); PolyPhen benign (0.187); catalogued as COSV58020458; called by muse, mutect2, varscan2
- STYXL2 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.499); catalogued as rs758006721, COSV54804983; called by muse, mutect2
- TAS2R16 | c.685C>A p.L229I | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99972217; called by muse, mutect2, varscan2
- TBC1D10C | c.779T>G p.F260C | Missense Mutation (SNP) | VAF 148/338 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56702799; called by muse, mutect2, varscan2
- TEX10 | c.2566G>T p.E856* | Nonsense Mutation (SNP) | VAF 66/260 reads (25%) | catalogued as COSV52441877; called by muse, mutect2, varscan2
- TG | c.8059G>C p.D2687H | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as COSV55075771; called by muse, mutect2, varscan2
- TOP2B | c.1039G>C p.V347L (on ENST00000264331 / NM_001330700.2; = p.V342L on NM_001068.3) | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV51971992; called by muse, mutect2, varscan2
- TRPM1 | c.4642C>G p.L1548V | Missense Mutation (SNP) | VAF 202/469 reads (43%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV56634348; called by muse, mutect2, varscan2
- TRPM2 | c.2980G>T p.E994* | Nonsense Mutation (SNP) | VAF 155/258 reads (60%) | catalogued as COSV55969541; called by muse, mutect2, varscan2
- UBE3A | c.1612G>T p.V538F | Missense Mutation (SNP) | VAF 51/399 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51665022; called by muse, mutect2, varscan2
- USP31 | c.3971C>T p.P1324L | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.019); catalogued as rs150676134; called by muse, mutect2, varscan2
- USP31 | c.3437A>G p.K1146R | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV54852079; called by muse, mutect2, varscan2
- VPS13A | c.8837G>A p.R2946K | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62429569; called by muse, mutect2, varscan2
- ZNF100 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV59747729; called by muse, mutect2, varscan2
- ZNF230 | c.1390G>C p.D464H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs369515636; called by muse, mutect2, varscan2
- ZNF425 | c.50A>G p.Y17C | Missense Mutation (SNP) | VAF 86/433 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65201296; called by muse, mutect2, varscan2
- ZNF711 | c.37C>G p.P13A | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV52153908; called by muse, mutect2, varscan2
- ZNF781 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.343); catalogued as COSV62201287; called by muse, mutect2
- COL1A2 | c.2463_2480del p.R822_P827del | In Frame Del (DEL) | VAF 48/360 reads (13%) | called by mutect2, pindel
- TP53 | c.792dup p.L265Tfs*7 | Frame Shift Ins (INS) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- TP53BP2 | c.2689_2691delinsTT p.P897Ffs*30 (on ENST00000343537 / NM_001031685.3; = p.P768Ffs*30 on NM_005426.2) | Frame Shift Del (DEL) | VAF 33/131 reads (25%) | called by pindel, varscan2*
- ALKBH7 | c.586C>A p.R196= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as COSV55532215; called by muse, mutect2, varscan2
- ARHGEF17 | c.2244A>G p.E748= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV55232418; called by muse, mutect2, varscan2
- ATP8A1 | c.1008C>A p.G336= | Silent (SNP) | VAF 45/245 reads (18%) | catalogued as COSV52534873, COSV52538002; called by muse, mutect2, varscan2
- CCDC18 | c.378G>A p.Q126= | Silent (SNP) | VAF 98/138 reads (71%) | catalogued as COSV58143366; called by muse, mutect2, varscan2
- CD226 | c.417C>T p.H139= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV54612121; called by muse, mutect2, varscan2
- CDRT15 | c.492C>G p.L164= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV69755527; called by mutect2, varscan2
- CNGA3 | c.1575C>A p.G525= | Silent (SNP) | VAF 87/217 reads (40%) | catalogued as COSV55624259; called by muse, mutect2, varscan2
- COL12A1 | c.6960C>A p.A2320= | Silent (SNP) | VAF 20/257 reads (8%) | catalogued as COSV59395785; called by muse, mutect2
- COL28A1 | c.1812G>A p.G604= | Silent (SNP) | VAF 61/207 reads (29%) | catalogued as COSV68082061; called by muse, mutect2, varscan2
- CSNK1D | c.381G>T p.R127= | Silent (SNP) | VAF 80/529 reads (15%) | catalogued as rs767499529, COSV53924418; called by muse, mutect2, varscan2
- DCAF12L2 | c.603C>G p.A201= | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as COSV63581609; called by muse, mutect2, varscan2
- DNAH3 | c.12180G>A p.L4060= | Silent (SNP) | VAF 36/261 reads (14%) | catalogued as COSV54520920; called by muse, mutect2, varscan2
- FAM111A | c.1368A>T p.L456= | Silent (SNP) | VAF 51/190 reads (27%) | catalogued as COSV64655341; called by muse, mutect2, varscan2
- FGA | c.1209G>A p.A403= | Silent (SNP) | VAF 76/248 reads (31%) | catalogued as rs775218633, COSV57394532; called by muse, mutect2, varscan2
- FLNA | c.2955T>A p.V985= | Silent (SNP) | VAF 44/185 reads (24%) | catalogued as COSV61042777, COSV61048227; called by muse, mutect2, varscan2
- IQCA1 | c.2325G>A p.A775= | Silent (SNP) | VAF 64/221 reads (29%) | catalogued as rs530031680, COSV54501773; called by muse, mutect2, varscan2
- JAKMIP2 | c.750G>T p.L250= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as COSV54604187; called by muse, mutect2, varscan2
- KDM4D | c.1182G>C p.G394= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV58634568; called by muse, mutect2, varscan2
- KIF21A | c.315C>T p.N105= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as rs963047462, COSV62771263; called by muse, mutect2, varscan2
- LCT | c.5469C>A p.I1823= | Silent (SNP) | VAF 26/178 reads (15%) | catalogued as COSV51549068; called by muse, mutect2, varscan2
- MXRA5 | c.6222G>T p.A2074= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs752606061, COSV54234788; called by muse, mutect2, varscan2
- NAA25 | c.2481A>G p.K827= | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as rs112342385, COSV55704199; called by muse, mutect2, varscan2
- PCDH19 | c.3387G>T p.L1129= (on ENST00000373034 / NM_001184880.2; = p.L1081= on NM_020766.3) | Silent (SNP) | VAF 76/409 reads (19%) | catalogued as COSV55262635; called by muse, mutect2, varscan2
- PCM1 | c.4785G>A p.R1595= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV59586633; called by muse, mutect2
- POLE | c.5511G>T p.L1837= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV57680038; called by muse, mutect2, varscan2
- PRDM1 | c.2047C>A p.R683= | Silent (SNP) | VAF 49/268 reads (18%) | catalogued as COSV100958675; called by muse, mutect2, varscan2
- PRLR | c.1443C>T p.S481= | Silent (SNP) | VAF 158/345 reads (46%) | catalogued as COSV51495585; called by muse, mutect2, varscan2
- PRSS35 | c.1038C>T p.T346= | Silent (SNP) | VAF 38/161 reads (24%) | catalogued as COSV63800524; called by muse, mutect2, varscan2
- PTK2 | c.234G>A p.K78= | Silent (SNP) | VAF 90/559 reads (16%) | catalogued as COSV61785592; called by muse, mutect2, varscan2
- RLN3 | c.135C>T p.F45= | Silent (SNP) | VAF 85/130 reads (65%) | catalogued as COSV54600706; called by muse, mutect2, varscan2
- SPTB | c.2961G>A p.L987= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as COSV67631729; called by muse, mutect2, varscan2
- TTN | c.8973A>T p.T2991= (on ENST00000591111; = p.T2945= on NM_003319.4) | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as COSV60050491; called by muse, mutect2, varscan2
- VEGFC | c.219C>G p.L73= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV54597996, COSV54605223; called by muse, mutect2, varscan2
- VEGFD | c.153G>A p.E51= | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as COSV52909583; called by muse, mutect2, varscan2
- ZMYND8 | c.9C>T p.I3= (on ENST00000311275 / NM_001363741.2; = p.I23= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/259 reads (15%) | catalogued as COSV53687399; called by muse, mutect2, varscan2
- ZNF251 | c.1944A>G p.K648= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs1460381641, COSV52957323; called by muse, mutect2, varscan2
- ARHGAP24 | c.391+7170G>A | Intron (SNP) | VAF 33/180 reads (18%) | catalogued as rs140557900, COSV99981964; called by muse, mutect2, varscan2
- BCAS3 | c.2075-4918C>T | Intron (SNP) | VAF 40/184 reads (22%) | catalogued as COSV101175673; called by muse, mutect2, varscan2
- BTNL8 | c.787+118C>A | Intron (SNP) | VAF 106/348 reads (30%) | catalogued as COSV99180449; called by muse, mutect2, varscan2
- FOLH1B | n.2067A>G | RNA (SNP) | VAF 109/216 reads (50%) | called by muse, mutect2, varscan2
- NXF5 | n.632C>A | RNA (SNP) | VAF 38/197 reads (19%) | catalogued as COSV53790886; called by muse, mutect2, varscan2
- PPP1R9A | c.2757+710T>A | Intron (SNP) | VAF 81/216 reads (38%) | catalogued as COSV56890714, COSV99195166; called by muse, mutect2, varscan2
- SLC35A2 | c.1163+112G>T | Intron (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99504173; called by muse, mutect2
- SNORD115-21 | n.37G>T | RNA (SNP) | VAF 128/480 reads (27%) | called by muse, mutect2, varscan2
- SNORD115-33 | n.1G>T | RNA (SNP) | VAF 137/384 reads (36%) | catalogued as rs1267998159; called by muse, mutect2, varscan2
